Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0IK, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0IK-01A (Primary Tumor).

1CB-0-3

Carcinoma, ductal, NOS, infiltrating 8500/3

Site Code: Breast, NOS C50.9 1/17/14

Patient

Surgical Pathology: Final

Surg Path

CLINICAL HISTORY:

Inflammatory breast cancer.

GROSS EXAMINATION:

A. "Biopsy of left breast", fresh. The specimen consists of a 2 x 0.6 cm ellipse of tan skin with underlying disc of subcutaneous tissue measuring 3 x 1.5 x 0.5 cm. Within the subcutaneous tissue is a firm, tan, ill-defined lesion measuring approximately 2.2 cm in greatest dimension. A portion of the specimen is submitted for ER/PR studies and to the tissue bank. The remainder of the specimen is sectioned and submitted in Block A1-A3.

Dr.

DIAGNOSIS:

A. "BIOPSY OF LEFT BREAST":

BREAST WITH INFILTRATING DUCTAL CARCINOMA (2.2 CM), N.S.A.B.P NUCLEAR GRADE MODERATELY-DIFFERENTIATED, HISTOLOGIC GRADE 3.

COMEDO TYPE INTRADUCTAL CARCINOMA IS PRESENT REPRESENTING 5% OF THE TOTAL TUMOR VOLUME.

LYMPHATIC/VASCULAR INVASION IS PRESENT, BUT NO TUMOR IS SEEN IN DERMAL LYMPHATICS.

SURGICAL MARGINS ARE POSITIVE FOR CARCINOMA.

Verified by:

Date

HIV-1A Discrepancy		X

Source: NCI Genomic Data Commons file 0145dccc-7933-4b85-ba42-a623c626b475 (TCGA-B6-A0IK.3A38A97C-2CBB-4802-9528-A4BBD62AEA4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).